Gene-level copy-number profile of tumor specimen TCGA-DX-A6YS-01A from TCGA case TCGA-DX-A6YS, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 61.1 years (22,310 days).
Specimen TCGA-DX-A6YS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ffae65f7-973f-462e-8dd6-165b8d6e21a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6YS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/096d7fbf-f63c-4c36-9d2f-7fc73e6104f3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 2,873; copy number 2: 12,076; copy number 3: 25,292; copy number 4: 10,746; copy number 5: 5,017; copy number 6: 1,965; copy number 7: 313; copy number 8: 751; copy number 9: 440; copy number 10: 36; copy number 12: 29; copy number 13: 88; copy number 15: 91; copy number 22: 2; copy number 23: 18; copy number 25: 2; copy number 27: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6YS-01A-12D-A350-01): tumor purity 0.84, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:118,436,490–118,572,970, 6 genes (within-gene range 0–2): KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30.
- chr17:31,008,497–31,382,116, 11 genes (within-gene range 0–1): AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,778 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,943,626–56,710,614, 49 genes, copy number 7–12: AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20.
- chr4:59,533,786–59,920,670, 6 genes, copy number 7: Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1.
- chr4:61,143,656–62,078,335, 6 genes, copy number 7 (within-gene range 2–7): LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA.
- chr4:64,606,418–64,767,897, 8 genes, copy number 7: MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1.
- chr4:72,807,267–77,611,834, 107 genes, copy number 9–25 (within-gene range 2–25) (broad region; genes not listed).
- chr4:81,919,995–82,129,656, 4 genes, copy number 12: COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13.
- chr5:124,808,981–125,602,227, 1 gene, copy number 8 (within-gene range 3–8): LINC02240.
- chr5:125,265,528–126,368,755, 8 genes, copy number 8 (within-gene range 4–8): HMGB1P22, AC116362.1, RN7SKP117, AC109471.1, AC116362.2, AC010587.2, AC010587.1, RPSAP37.
- chr5:157,565,964–157,605,637, 3 genes, copy number 8: AC106801.1, RNU6-390P, AC008694.2.
- chr5:172,325,000–172,559,202, 3 genes, copy number 8: SH3PXD2B, AC011407.1, LINC01944.
- chr5:172,690,454–181,342,213, 290 genes, copy number 7–22 (broad region; genes not listed).
- chr6:128,639,188–137,763,984, 163 genes, copy number 9–15 (within-gene range 2–15) (broad region; genes not listed).
- chr6:137,823,673–137,903,576, 3 genes, copy number 8: WAKMAR2, TNFAIP3, AL591468.1.
- chr6:137,995,270–138,344,663, 4 genes, copy number 10 (within-gene range 7–10): RPSAP42, PERP, ARFGEF3, PBOV1.
- chr6:138,422,043–148,018,985, 120 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr6:150,504,811–166,906,451, 251 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr7:18,086,949–23,275,108, 67 genes, copy number 7–23 (broad region; genes not listed).
- chr7:28,299,321–37,951,936, 171 genes, copy number 9–22 (within-gene range 5–22) (broad region; genes not listed).
- chr7:38,383,704–43,807,342, 65 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr7:44,467,897–46,000,898, 49 genes, copy number 8: AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD, TBRG4, SNORA5A, SNORA5C, SNORA5B, RAMP3, AC073968.2, AC073968.1, ELK1P1, AC073325.1, AC073325.2, ADCY1, SEPTIN7P2, GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, CCDC201, IGFBP1, IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1.
- chr7:79,768,028–83,664,625, 32 genes, copy number 13–27 (within-gene range 3–27): GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2.
- chr8:58,805,412–59,123,478, 4 genes, copy number 8: TOX, RNU4-50P, AC105150.1, AC090152.1.
- chr8:59,821,124–64,383,787, 61 genes, copy number 8 (broad region; genes not listed).
- chr8:73,042,910–77,014,028, 70 genes, copy number 7 (broad region; genes not listed).
- chr8:114,282,067–115,809,673, 5 genes, copy number 7: AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1.
- chr8:116,022,686–116,022,779, 1 gene, copy number 7: RNA5SP276.
- chr10:18,513,115–23,586,224, 87 genes, copy number 7 (broad region; genes not listed).
- chr11:91,382,909–93,197,991, 22 genes, copy number 8: AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5.
- chr12:85,014,311–89,418,559, 42 genes, copy number 8: TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1.
- chr12:91,632,912–94,835,158, 71 genes, copy number 7 (broad region; genes not listed).
- chr18:77,863,464–78,140,887, 5 genes, copy number 7: RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1.

Autosomal genes at a single copy (total copy number 1): 1,954. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
